Somatic mutation profile of tumor specimen TARGET-40-0A4I3S-01A (aliquot TARGET-40-0A4I3S-01A-01D) from TARGET case TARGET-40-0A4I3S, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Age at diagnosis: 22.8 years (8,313 days).
Specimen TARGET-40-0A4I3S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9eccc9ed-18dc-4628-90c9-01ebb6cca4b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4I3S-10A (Blood Derived Normal), aliquot TARGET-40-0A4I3S-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25f7678f-c0f6-4efc-b544-0fee6ce88d47

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MED13 | c.2113G>C p.E705Q | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV67266542; called by mutect2, varscan2
- JADE3 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- Y_RNA | chrX:71492438 C>A | 5'Flank (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
